FM case AD2049 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/977baf33-4ebc-4b8b-b66c-dd7884e96b68

Female, 74.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
